Somatic mutation profile of tumor specimen 0DS6L7 from CCDI case PBCHRE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (633 days).
Specimen 0DS6L7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8697e153-23e9-4609-9b7b-504bf2fd725a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS6LL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e52b4b5-3729-4e59-b7f7-57cff663f0be

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMO | c.1604G>T p.W535L | Missense Mutation (SNP) | VAF 203/425 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121918347, COSV50824509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 131/333 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1489602094, COSV56408549; called by muse, mutect2, varscan2
- CSPP1 | c.2083+4C>T | Splice Region (SNP) | VAF 87/194 reads (45%) | catalogued as rs779380282; called by muse, mutect2, varscan2
- TYW3 | c.175-41A>G | Intron (SNP) | VAF 98/172 reads (57%) | called by muse, mutect2, varscan2
